Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A7U0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A7U0-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

ICD-O-3

Paraganglioma, extra-adrenal
869B/1

Site: Retroperitoneum
C48.0

Q25/14/14

Diagnosis:

A: Retroperitoneal mass and right adrenal gland, resection
- Extra-adrenal sympathetic paraganglioma, maximum tumor size
3.3 cm, margins negative (See Comment).
- Benign adrenal gland.

Comment:

Special stains support the diagnosis. The neoplasm demonstrates
diffuse strong positivity for synaptophysin and chromogranin. S-
100 highlights an intact sustentacular cell network.

Clinical History:

The patient is a -year-old man with retroperitoneal
paraganglioma just caudal to the right adrenal gland.

Gross Description:

Received is one appropriately labeled container, additionally
labeled "right
adrenal paraganglioma" is a 25 gram 6.4 x 5.7 x 2.2 cm overall
fragment of
un-oriented yellow/tan fibrofatty tissue is inked and sectioned
to reveal a 3.3
x 2.9 x 1.7 cm solid yellow/brown circumscribed nodule adjacent
to a 4.7 x 3.4 x
1.2 cm fragment of focally disrupted adrenal gland. The nodule
appears to abut
the adrenal gland but not arise from or invade into it.
Representative
sections are submitted in blocks A1-A6, tissue remains in
formalin.

Light Microscopy:

Light microscopic examination is performed by Dr.

Sections reveal a bland cellular neoplasm arising in the soft
tissue adjacent to the adrenal gland. The tumor is distinct and
separate from the adrenal gland. The tumor demonstrates a
histologic pattern typical of paraganglioma with a zellballen
morphology. Histologic features are low grade and do not
indicate definite malignant features.

Reviewer Initials	Q25/14/13	

Source: NCI Genomic Data Commons file 88309283-39c9-491c-9662-8ee195cd0b8d (TCGA-QT-A7U0.88CBB410-A2AD-4AA6-BB8D-1D92D8BFF95E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).